Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042792-09A.2 (aliquot TARGET-15-SJMPAL042792-09A.2-01D) from TARGET case TARGET-15-SJMPAL042792, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,527 days).
Specimen TARGET-15-SJMPAL042792-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3aa4830-e5a7-42e6-892c-698e7052ca7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042792-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042792-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d4634d7-ce1b-46d6-a8fc-8373d57a8de4

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161430, COSV64198920; called by muse, mutect2
- CHRM1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756528929, COSV61006252; called by muse, mutect2, varscan2
- DLL4 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs774301166, COSV51061515; called by muse, mutect2, varscan2
- EHBP1 | c.3595C>A p.Q1199K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.988); catalogued as COSV50420228; called by muse, mutect2
- HELZ2 | c.4001G>T p.R1334L (on ENST00000467148 / NM_001037335.2; = p.R765L on NM_033405.3) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.878); catalogued as rs891024434; called by muse, mutect2
- IGSF1 | c.2909A>G p.K970R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV63836246; called by muse, mutect2
- MROH5 | c.2800G>T p.V934L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV71302628; called by muse, mutect2
- LRRN2 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2
- MACF1 | c.4193T>G p.L1398* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- PARD6A | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNA3 | c.3099C>A p.S1033R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP3 | c.639C>A p.G213= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- SMPDL3B | c.1299C>A p.G433= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SYP | c.693G>T p.P231= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV54295986; called by muse, mutect2
- THSD7A | c.1344C>T p.R448= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs776774107, COSV101448556; called by muse, mutect2, varscan2
- TRIM2 | c.1101C>A p.A367= (on ENST00000437508; = p.A394= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- AC245033.1 | c.1174+738G>A | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as rs989141339; called by muse, mutect2, varscan2
- LINC02694 | n.361C>A | RNA (SNP) | VAF 4/28 reads (14%) | catalogued as rs916902292; called by muse, varscan2
